Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7605, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7605-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

Sections demonstrate a variably cellular glial neoplasm that diffusely infiltrates the gray and white matter. The majority of the tumor is only mildly hypercellular but some areas having confluent hypercellularity are seen. The tumor cells have mildly atypical, enlarged, round nuclei and either perinuclear halos or microgemistocytic cytoplasm. Only a single mitosis is seen after extensive examination. There is no microvascular proliferation or necrosis.

Addendum Description: Scattered MIB-1 reactive cells are present in the most proliferative areas with a calculated labeling index of 0.6%

Addendum Diagnosis: Low grade Oligodendroglioma (Who Grade II)
MIB-1 Labeling Index= 0.6%

Source: NCI Genomic Data Commons file 12c0a1ad-b707-404d-ba8d-2de552d61ef0 (TCGA-HT-7605.820C0259-C976-48CC-AF5A-3E2BC11BD4E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).